Somatic mutation profile of tumor specimen MMRF_2779_1_BM_CD138pos (aliquot MMRF_2779_1_BM_CD138pos_T1_KHS5U_L15727) from MMRF case MMRF_2779, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.0 years (22,274 days).
Specimen MMRF_2779_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34d5dbf4-0377-4939-9896-a21468cd2b0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2779_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2779_1_PB_WBC_C3_KHS5U_L15771; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45db71ff-2ebb-4208-8ce8-5ab176b0f9c0

The open-access MAF lists 104 somatic variants for this specimen: 41 protein-altering or splice-affecting, 13 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 30, Silent 13, Intron 12, 5'UTR 3, 3'Flank 3, Splice Site 2, Splice Region 1, Frame Shift Ins 1, 5'Flank 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 79/265 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CACNA2D1 | c.1949C>A p.P650Q (on ENST00000356253 / NM_001366867.1; = p.P638Q on NM_000722.4) | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs1245193680; called by muse, mutect2, varscan2
- CAPN11 | c.1472C>T p.T491M | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs772128584; called by muse, mutect2, varscan2
- CDC37 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 86/134 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.279); catalogued as rs771845881, COSV55767790; called by muse, mutect2, varscan2
- DCC | c.2186C>T p.P729L | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100499126; called by muse, mutect2, varscan2
- DDX3X | c.1226C>G p.S409C (on ENST00000399959; = p.S410C on NM_001356.5) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV67863744; called by muse, mutect2, varscan2
- DISP2 | c.43G>C p.A15P | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.206); catalogued as rs1032606830; called by muse, mutect2
- FAT4 | c.3613G>T p.D1205Y | Missense Mutation (SNP) | VAF 75/147 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67898365; called by muse, mutect2, varscan2
- GCDH | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as rs1442597198; called by muse, mutect2
- HS6ST3 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs778619413, COSV65009566; called by muse, mutect2, varscan2
- MUC2 | c.2137G>A p.V713I | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs200274846; called by muse, mutect2, varscan2
- NPLOC4 | c.976del p.R326Afs*11 | Frame Shift Del (DEL) | VAF 48/174 reads (28%) | catalogued as COSV58615558; called by mutect2, pindel, varscan2
- NUP42 | c.212dup p.S72Qfs*13 | Frame Shift Ins (INS) | VAF 56/141 reads (40%) | catalogued as rs758695627; called by mutect2, varscan2
- PCDHA6 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.077); catalogued as rs781879860, COSV65341531; called by muse, mutect2, varscan2
- PRICKLE1 | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs886042287, COSV58203658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMHD1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as rs1455837248; ClinVar: uncertain significance; called by muse, mutect2
- SIGLEC6 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 67/249 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58437815; called by muse, mutect2, varscan2
- SPATC1L | c.778C>T p.R260C (on ENST00000291672 / NM_001142854.2; = p.R106C on NM_032261.5) | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs569907908; called by muse, mutect2, varscan2
- SUV39H1 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61920977; called by muse, mutect2, varscan2
- TCTN3 | c.167C>G p.T56S | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.112); catalogued as rs1180918361; called by muse, mutect2
- VSTM2B | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1337753359, COSV59259822; called by muse, varscan2
- ADAMTS14 | c.1322G>T p.C441F | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ANKRD13C | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 11/235 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.059); called by muse, mutect2
- CADPS | c.3646G>T p.A1216S | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CFAP410 | c.614G>A p.R205K | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CTNNA3 | c.1046A>C p.N349T | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- ECPAS | c.2745A>C p.Q915H | Missense Mutation (SNP) | VAF 173/289 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- FMO5 | c.1516A>G p.R506G | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- GLT8D1 | c.911A>T p.N304I | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- GLT8D1 | c.812+7A>C | Splice Region (SNP) | VAF 35/132 reads (27%) | called by muse, mutect2, varscan2
- GTF2IRD1 | c.1015G>T p.D339Y | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- H2AC8 | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- INPP5D | c.1136A>G p.K379R (on ENST00000445964 / NM_001017915.3; = p.K378R on NM_005541.5) | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.754); called by muse, mutect2
- LDHC | c.138T>G p.D46E | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- LZIC | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.433); called by muse, mutect2
- RBM20 | c.3574-1G>T p.X1192_splice | Splice Site (SNP) | VAF 33/84 reads (39%) | called by muse, mutect2, varscan2
- SCAF1 | c.2977C>T p.Q993* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- SSH3 | c.1766T>C p.V589A | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAF2 | c.189-1G>C p.X63_splice | Splice Site (SNP) | VAF 74/199 reads (37%) | called by muse, mutect2, varscan2
- UNC13C | c.4601G>A p.S1534N | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XPO7 | c.1600A>C p.T534P | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CCNB1 | c.501T>C p.C167= | Silent (SNP) | VAF 9/147 reads (6%) | called by muse, mutect2
- DDX60L | c.5040G>A p.L1680= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as rs748397533; called by muse, mutect2, varscan2
- DGKA | c.2035C>T p.L679= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- DNAH1 | c.6705C>A p.L2235= | Silent (SNP) | VAF 28/412 reads (7%) | catalogued as rs1470340287; called by muse, mutect2
- ISM2 | c.1320C>T p.S440= | Silent (SNP) | VAF 76/127 reads (60%) | called by muse, mutect2, varscan2
- KDR | c.1404C>T p.N468= | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as rs141384787; called by muse, mutect2, varscan2
- MICAL2 | c.1062A>G p.L354= | Silent (SNP) | VAF 138/216 reads (64%) | called by muse, mutect2, varscan2
- MSR1 | c.774T>C p.D258= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV50534655; called by mutect2, varscan2
- MYZAP | c.1185A>T p.I395= | Silent (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- RXFP2 | c.888T>C p.V296= | Silent (SNP) | VAF 54/145 reads (37%) | called by muse, mutect2, varscan2
- SMCHD1 | c.4479T>G p.P1493= | Silent (SNP) | VAF 108/262 reads (41%) | called by muse, varscan2
- UGT2A3 | c.231C>T p.V77= | Silent (SNP) | VAF 52/160 reads (33%) | called by muse, mutect2, varscan2
- VWCE | c.2757C>A p.R919= | Silent (SNP) | VAF 34/139 reads (24%) | catalogued as COSV57112096; called by muse, mutect2, varscan2
- ADARB1 | c.*120G>A | 3'UTR (SNP) | VAF 12/193 reads (6%) | catalogued as rs1455268676; called by muse, mutect2
- ALDOC | chr17:28571623 C>G | 3'Flank (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- ASB1 | c.*4964T>G | 3'UTR (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- ATG9B | c.963+105G>A | Intron (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- BMPR1B | chr4:95155240 T>C | 3'Flank (SNP) | VAF 40/88 reads (45%) | called by muse, mutect2, varscan2
- CBY2 | c.156+337T>A | Intron (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- CLU | c.*627G>C | 3'UTR (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- CORO2A | c.*2737C>G | 3'UTR (SNP) | VAF 82/287 reads (29%) | called by muse, mutect2, varscan2
- DDAH2 | c.-60-278G>A | Intron (SNP) | VAF 14/141 reads (10%) | called by muse, mutect2
- DDX39B | c.-115T>C | 5'UTR (SNP) | VAF 33/73 reads (45%) | catalogued as rs1362362081; called by muse, mutect2, varscan2
- DGKA | c.1587+100A>G | Intron (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- GJB7 | c.*619G>C | 3'UTR (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- GSK3A | c.283+590C>G | Intron (SNP) | VAF 8/111 reads (7%) | called by muse, mutect2
- HEATR5A | c.*109G>C | 3'UTR (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2, varscan2
- HMBOX1 | c.*796G>A | 3'UTR (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- HMGB4 | c.-1257G>A | 5'UTR (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- ITGA9 | c.*3862C>T | 3'UTR (SNP) | VAF 40/106 reads (38%) | catalogued as rs1037083472; called by muse, varscan2
- KCNA6 | c.*39T>C | 3'UTR (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- KRTAP2-1 | c.*317A>T | 3'UTR (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- LINC02873 | n.2697G>A | RNA (SNP) | VAF 9/81 reads (11%) | catalogued as rs867635747; called by muse, mutect2, varscan2
- LRFN5 | c.*368G>A | 3'UTR (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2
- MAP3K13 | c.*728A>C | 3'UTR (SNP) | VAF 51/81 reads (63%) | called by muse, mutect2, varscan2
- MIR1915 | chr10:21497028 C>T | 5'Flank (SNP) | VAF 12/156 reads (8%) | catalogued as rs1455975218; called by muse, mutect2
- NAV2 | chr11:20119194 T>C | 3'Flank (SNP) | VAF 6/146 reads (4%) | catalogued as COSV60656441; called by muse, mutect2
- NDUFAF5 | c.*24T>C | 3'UTR (SNP) | VAF 106/295 reads (36%) | called by muse, mutect2, varscan2
- NET1 | c.256-5201G>A | Intron (SNP) | VAF 28/73 reads (38%) | catalogued as COSV61791066; called by muse, mutect2, varscan2
- NME3 | c.178-31T>G | Intron (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- NPL | c.*930A>C | 3'UTR (SNP) | VAF 49/99 reads (49%) | called by muse, mutect2, varscan2
- NPNT | c.*1261C>T | 3'UTR (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- NTN4 | c.*1141T>C | 3'UTR (SNP) | VAF 32/78 reads (41%) | called by muse, mutect2, varscan2
- NTRK2 | c.1397-52985G>A | Intron (SNP) | VAF 7/149 reads (5%) | called by muse, mutect2
- PDCD4 | c.*1360A>G | 3'UTR (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- PPHLN1 | c.1024+87C>T | Intron (SNP) | VAF 47/146 reads (32%) | catalogued as rs369230169; called by muse, mutect2, varscan2
- PTK2 | c.1418-32G>A | Intron (SNP) | VAF 6/14 reads (43%) | catalogued as rs878967669; called by muse, varscan2
- RPL13 | c.*1217C>T | 3'UTR (SNP) | VAF 21/152 reads (14%) | catalogued as rs1567942814; called by muse, mutect2, varscan2
- SEMA3E | c.*436T>G | 3'UTR (SNP) | VAF 43/93 reads (46%) | called by muse, mutect2, varscan2
- SEMA3E | c.*15C>G | 3'UTR (SNP) | VAF 33/394 reads (8%) | called by muse, mutect2
- SHMT2 | c.*480C>T | 3'UTR (SNP) | VAF 10/151 reads (7%) | called by muse, mutect2
- SPTSSA | c.*1512G>A | 3'UTR (SNP) | VAF 8/17 reads (47%) | catalogued as rs1421838968; called by muse, mutect2, varscan2
- ST18 | c.*65G>T | 3'UTR (SNP) | VAF 8/56 reads (14%) | catalogued as COSV52490363; called by muse, mutect2, varscan2
- SUSD5 | c.*313T>C | 3'UTR (SNP) | VAF 16/32 reads (50%) | catalogued as rs1187367341; called by muse, mutect2, varscan2
- TARS3 | c.-57C>T | 5'UTR (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- TBC1D14 | c.*1890G>A | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- TMPRSS11D | c.*1429T>C | 3'UTR (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- TRIM29 | c.1627+1248G>A | Intron (SNP) | VAF 14/90 reads (16%) | catalogued as rs983504863; called by muse, mutect2
- TRIOBP | c.6324+535_6324+552del | Intron (DEL) | VAF 31/90 reads (34%) | called by mutect2, pindel, varscan2
- TTC3 | c.*221C>T | 3'UTR (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2, varscan2
- UBE3C | c.*735G>C | 3'UTR (SNP) | VAF 9/202 reads (4%) | called by muse, mutect2
- USP34 | c.*439A>C | 3'UTR (SNP) | VAF 12/43 reads (28%) | catalogued as rs541132321; called by muse, mutect2, varscan2
- USP53 | c.*1321T>G | 3'UTR (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
